Somatic mutation profile of tumor specimen TCGA-OR-A5LC-01A (aliquot TCGA-OR-A5LC-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LC, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 71.4 years (26,084 days).
Specimen TCGA-OR-A5LC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e58abf1-cf0f-4881-9d0d-8c247ccaace1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LC-10A (Blood Derived Normal), aliquot TCGA-OR-A5LC-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b53d72e4-4139-4390-aa0c-59b671d9e1c3

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 2, Splice Site 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCORL1 | c.3586C>T p.R1196* | Nonsense Mutation (SNP) | VAF 140/281 reads (50%) | catalogued as rs755020390, COSV54390382; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C12orf65 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207537130; called by muse, mutect2, varscan2
- CSMD3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV52327027; called by muse, mutect2, varscan2
- FAM3D | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs759070186; called by muse, varscan2
- GPAM | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as rs754776897, COSV62081126; called by muse, mutect2, varscan2
- ITGB8 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs374723970; called by muse, varscan2
- KLF5 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV66613955; called by muse, mutect2, varscan2
- MAP7D3 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV60170543; called by muse, mutect2, varscan2
- MYO10 | c.5434C>A p.H1812N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57027271; called by muse, mutect2, varscan2
- NRG3 | c.2029G>A p.A677T (on ENST00000404547 / NM_001370084.1; = p.A653T on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.047); catalogued as rs1009259285; called by muse, mutect2, varscan2
- NSD2 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs192103195; called by muse, mutect2, varscan2
- PIK3AP1 | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV59531101; called by muse, mutect2, varscan2
- TRPC3 | c.765G>T p.K255N (on ENST00000379645 / NM_001366479.2; = p.K182N on NM_003305.2) | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99312440; called by muse, mutect2, varscan2
- AL592490.1 | c.1457A>G p.E486G | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ATXN2L | c.1955+1G>T p.X652_splice | Splice Site (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- C9 | c.1180A>T p.I394F | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, varscan2
- IFT52 | c.414-1G>T p.X138_splice | Splice Site (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- IL13RA1 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INSM2 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX4 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 74/95 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MIDEAS | c.2560del p.L854Wfs*5 | Frame Shift Del (DEL) | VAF 46/73 reads (63%) | called by mutect2, pindel, varscan2
- MROH2B | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO1F | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.17062G>A p.D5688N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR7A10 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDE8A | c.1156_1157del p.S386Hfs*4 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- POC1B-GALNT4 | c.1715G>A p.S572N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SEC14L4 | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2
- TLN1 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 83/97 reads (86%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TRPM4 | c.2417A>G p.Q806R | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13A | c.6544A>T p.S2182C | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- DPRX | c.495C>G p.P165= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as COSV64949942; called by muse, mutect2, varscan2
- FLG | c.7281C>A p.A2427= | Silent (SNP) | VAF 108/446 reads (24%) | catalogued as COSV64249833; called by muse, mutect2, varscan2
- KCNE4 | c.486C>T p.P162= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs768989498; called by muse, varscan2
- OR1D5 | c.720C>A p.T240= | Silent (SNP) | VAF 252/642 reads (39%) | catalogued as rs751494152; called by muse, mutect2, varscan2
- PCDH18 | c.1218A>G p.K406= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- PNLIP | c.996T>G p.P332= | Silent (SNP) | VAF 56/121 reads (46%) | called by muse, mutect2, varscan2
- RGS19 | c.234G>A p.T78= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as rs939358450, COSV58658261; called by muse, mutect2, varscan2
- SHANK1 | c.2763C>A p.P921= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV53251704; called by muse, mutect2, varscan2
- UBE3C | c.2628C>T p.Y876= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as rs980298476, COSV61956406; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-23804T>C | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
